Somatic mutation profile of tumor specimen TCGA-13-0894-01B (aliquot TCGA-13-0894-01B-01W-0492-08) from TCGA case TCGA-13-0894, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.3 years (19,466 days).
Specimen TCGA-13-0894-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c96bded-d0b9-4922-b3f8-729b31d671d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0894-10A (Blood Derived Normal), aliquot TCGA-13-0894-10A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5445b232-ccd8-4737-9ef6-dc3cc053219f

The open-access MAF lists 87 somatic variants for this specimen: 67 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 18, Nonsense Mutation 3, Splice Site 3, Splice Region 1, Frame Shift Del 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 23/83 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.1526T>C p.L509P | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as rs1385693209, COSV100266698; called by muse, mutect2
- ADAMTS14 | c.2035G>A p.V679I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0.012); catalogued as rs149001845, COSV64602374; called by muse, mutect2
- ADAMTS8 | c.2544C>A p.C848* | Nonsense Mutation (SNP) | VAF 9/148 reads (6%) | catalogued as COSV57296303, COSV99960750; called by muse, mutect2
- ADGRG6 | c.358T>G p.F120V | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV51591081; called by muse, mutect2, varscan2
- ATAD5 | c.4403T>G p.I1468S | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV58974063; called by muse, mutect2, varscan2
- ATPAF2 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV100572705; called by muse, mutect2
- BCL6 | c.2030T>C p.L677S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99215580; called by muse, mutect2
- BRINP2 | c.2033T>G p.M678R | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100838034; called by muse, mutect2
- C14orf39 | c.1634C>T p.T545I | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); catalogued as rs1429265123, COSV58781516; called by muse, mutect2, varscan2
- CENPF | c.7587T>G p.N2529K | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV65274620; called by muse, mutect2, varscan2
- CGNL1 | c.1463G>A p.G488D | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV55567111; called by muse, mutect2, varscan2
- CHMP4C | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51926958; called by muse, mutect2, varscan2
- COL22A1 | c.1730C>G p.P577R | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100277863, COSV99079042; called by muse, mutect2
- DMXL1 | c.8054T>C p.I2685T | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs920039141, COSV100223781; called by muse, mutect2, varscan2
- DYNC1I2 | c.344A>T p.H115L | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.194); catalogued as COSV55525686; called by muse, mutect2, varscan2
- EFR3A | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as COSV54456391; called by muse, mutect2, varscan2
- EHHADH | c.2160C>G p.S720R | Missense Mutation (SNP) | VAF 110/438 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51629860; called by muse, mutect2, varscan2
- FARSA | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765172401, COSV53367504; called by muse, mutect2, varscan2
- FNDC3B | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV100394012; called by muse, mutect2
- FOXR1 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 14/440 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100392895; called by muse, mutect2
- GABRA6 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV50877559; called by muse, mutect2, varscan2
- GFRAL | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 184/1426 reads (13%) | catalogued as COSV61228659; called by muse, varscan2
- GFRAL | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 84/515 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV100475013; called by muse, varscan2
- GOLGA4 | c.3641C>G p.A1214G | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.225); catalogued as COSV62710470; called by muse, mutect2, varscan2
- GPNMB | c.1141A>G p.I381V (on ENST00000381990 / NM_001005340.2; = p.I369V on NM_002510.3) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV99326442; called by muse, mutect2, varscan2
- GTDC1 | c.738G>C p.L246F | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV53989096; called by muse, mutect2, varscan2
- IGF2BP3 | c.542G>T p.R181M | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV51683753, COSV51694098; called by muse, mutect2, varscan2
- ILVBL | c.524T>A p.F175Y | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV54619347; called by muse, mutect2, varscan2
- IVNS1ABP | c.96T>A p.C32* | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | catalogued as COSV62249982; called by muse, varscan2
- L3MBTL3 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs940968246, COSV62385915; called by muse, mutect2, varscan2
- MAP4K3 | c.2379T>C p.C793= | Splice Region (SNP) | VAF 6/24 reads (25%) | catalogued as COSV55712529; called by muse, mutect2, varscan2
- OPN5 | c.756+1G>C p.X252_splice | Splice Site (SNP) | VAF 64/450 reads (14%) | catalogued as COSV55245315; called by muse, varscan2
- OR11H6 | c.9T>G p.F3L | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV59644121; called by muse, mutect2, varscan2
- OR2A12 | c.790A>G p.S264G | Missense Mutation (SNP) | VAF 104/1071 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.158); catalogued as COSV68821359; called by muse, mutect2
- OR2T33 | c.951C>A p.H317Q | Missense Mutation (SNP) | VAF 66/534 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV58815178; called by muse, mutect2, varscan2
- PAN2 | c.1865C>G p.T622S | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.048); catalogued as COSV99228240; called by muse, mutect2
- PEG3 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 124/550 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs146466276; called by muse, mutect2, varscan2
- PKD1L1 | c.5444A>G p.K1815R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as COSV99219333; called by muse, mutect2, varscan2
- PKHD1L1 | c.4061G>C p.G1354A | Missense Mutation (SNP) | VAF 72/530 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65742098; called by muse, mutect2, varscan2
- PLXNA2 | c.866A>T p.K289M | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV104424163, COSV65440190; called by muse, mutect2, varscan2
- PNLIPRP1 | c.572C>A p.T191K | Missense Mutation (SNP) | VAF 114/387 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62611666; called by muse, mutect2, varscan2
- POLQ | c.1831C>G p.P611A | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV51750700; called by muse, varscan2
- PPARA | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.08); catalogued as COSV53078262; called by muse, mutect2, varscan2
- PPP2R3C | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs914955161, COSV54832489; called by muse, mutect2, varscan2
- PRRG2 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99882384; called by muse, mutect2
- PTCD1 | c.387G>T p.W129C | Missense Mutation (SNP) | VAF 155/632 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as COSV52857383; called by muse, mutect2, varscan2
- R3HDM2 | c.2354T>A p.L785H | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1301004452, COSV61288145; called by muse, mutect2, varscan2
- RASSF2 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65082062; called by muse, mutect2, varscan2
- RHOD | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV100448062; called by muse, mutect2
- SAFB | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs753148563, COSV52651136; called by muse, mutect2, varscan2
- SESN2 | c.1414C>G p.L472V | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99455641; called by muse, mutect2
- SLC9A7 | c.2072C>T p.T691M | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs371727694, COSV60378793; called by muse, mutect2, varscan2
- SOAT2 | c.1359C>A p.F453L | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100037422; called by muse, mutect2, varscan2
- STYXL2 | c.1631T>A p.L544Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54804616; called by muse, mutect2, varscan2
- SYT10 | c.152-2A>G p.X51_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as COSV57339899; called by muse, mutect2
- TAF5L | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV99273049; called by muse, mutect2
- TFB2M | c.1160G>C p.W387S | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63624914; called by muse, mutect2
- TMCC2 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100319281; called by muse, mutect2, varscan2
- TRIM67 | c.1879A>G p.N627D | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV64158734; called by muse, mutect2, varscan2
- TRPC3 | c.1142G>C p.R381P (on ENST00000379645 / NM_001366479.2; = p.R308P on NM_003305.2) | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53374898, COSV53375138; called by muse, mutect2, varscan2
- TSC22D1 | c.2993C>T p.A998V (on ENST00000458659 / NM_183422.4; = p.A69V on NM_006022.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779260235, COSV54925451; called by mutect2, varscan2
- WWC1 | c.1324C>A p.L442I | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV99514804; called by muse, mutect2
- ZNF561 | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 145/637 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.977); catalogued as COSV57177652; called by muse, mutect2, varscan2
- ECD | c.526_530del p.A176Ffs*16 | Frame Shift Del (DEL) | VAF 17/137 reads (12%) | called by mutect2, pindel, varscan2
- EPOR | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SLC4A2 | c.2192-2A>G p.X731_splice | Splice Site (SNP) | VAF 6/33 reads (18%) | called by mutect2, varscan2
- ADGRV1 | c.11220C>A p.T3740= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV67984258; called by muse, mutect2, varscan2
- CD36 | c.1374T>C p.A458= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV59210410, COSV59212593; called by muse, mutect2, varscan2
- CFAP65 | c.2160T>G p.P720= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV58560075, COSV58560507; called by muse, mutect2, varscan2
- CXCL2 | c.210C>T p.A70= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs1381776427, COSV99933196; called by muse, mutect2, varscan2
- FAM171A1 | c.1215C>A p.G405= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV65315128; called by muse, mutect2
- GFM1 | c.928T>C p.L310= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as rs1188969241, COSV51832433; called by muse, mutect2, varscan2
- GJB1 | c.177C>T p.G59= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100661263; called by muse, mutect2, varscan2
- MMP10 | c.30G>A p.L10= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as rs775492000, COSV99666500; called by muse, mutect2
- NLRP7 | c.1824C>G p.S608= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100052345; called by muse, mutect2
- OAT | c.531C>T p.F177= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV100920416; called by muse, mutect2, varscan2
- PDP2 | c.1491A>C p.T497= | Silent (SNP) | VAF 14/48 reads (29%) | called by mutect2, varscan2
- PPM1G | c.1230C>T p.N410= | Silent (SNP) | VAF 180/337 reads (53%) | catalogued as COSV59769331; called by muse, mutect2, varscan2
- ROBO4 | c.843G>T p.T281= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as rs138055137, COSV100127510; called by muse, mutect2
- SPAM1 | c.1461C>T p.S487= | Silent (SNP) | VAF 35/351 reads (10%) | catalogued as COSV56143188; called by muse, mutect2, varscan2
- TLR8 | c.1536G>T p.L512= (on ENST00000218032 / NM_138636.5; = p.L530= on NM_016610.4) | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV54317664; called by muse, mutect2, varscan2
- TRAV19 | c.165C>T p.F55= | Silent (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- ZNF227 | c.1618C>A p.R540= | Silent (SNP) | VAF 10/246 reads (4%) | catalogued as rs1299282863, COSV57313834; called by muse, mutect2
- ZNF248 | c.180C>T p.I60= | Silent (SNP) | VAF 59/340 reads (17%) | catalogued as rs1320031869, COSV61997609; called by muse, mutect2, varscan2
- CEP112 | c.2394+25521G>T | Intron (SNP) | VAF 70/912 reads (8%) | catalogued as COSV100439092; called by muse, mutect2
- RN7SL484P | chr15:99791700 C>T | 3'Flank (SNP) | VAF 7/30 reads (23%) | catalogued as rs1206875333; called by muse, mutect2, varscan2
